Gene-level copy-number profile of tumor specimen C3L-01138-01 from CPTAC case C3L-01138, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 62.2 years (22,715 days).
Specimen C3L-01138-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 77aae578-6ed6-4a28-89c2-f9a43a0cb1cb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01138-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,867 have no estimate.
https://portal.gdc.cancer.gov/files/d2076281-afbf-4050-a507-fb8af3d81e22

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 365; copy number 1: 885; copy number 2: 13,816; copy number 3: 28,675; copy number 4: 10,877; copy number 5: 1,911; copy number 6: 1,109; copy number 7: 364; copy number 8: 21; copy number 9: 405; copy number 10: 134; copy number 13: 15; copy number 15: 63; copy number 16: 20; copy number 17: 6; copy number 20: 31; copy number 28: 59.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,118 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,081,316–42,996,814, 124 genes, copy number 7–10 (broad region; genes not listed).
- chr1:58,933,643–65,067,754, 89 genes, copy number 8–28 (within-gene range 3–28) (broad region; genes not listed).
- chr3:93,843,764–93,980,003, 2 genes, copy number 8 (within-gene range 3–8): RNU6-488P, PROS1.
- chr7:6,080,704–6,491,098, 11 genes, copy number 8: AC004895.1, USP42, CYTH3, Y_RNA, FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1.
- chr7:56,805,336–66,906,297, 240 genes, copy number 7 (broad region; genes not listed).
- chr7:96,283,357–109,597,166, 341 genes, copy number 9 (broad region; genes not listed).
- chr9:63,832,127–63,859,641, 1 gene, copy number 10: FRG1JP.
- chr11:68,870,664–74,949,200, 209 genes, copy number 7–20 (within-gene range 2–20) (broad region; genes not listed).
- chr11:74,931,724–74,936,937, 1 gene, copy number 7: AP001992.2.
- chr18:45,034–4,459,458, 100 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
